Somatic mutation profile of tumor specimen BA2491D (aliquot aq-BA2491D) from BEATAML1.0 case 2124, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.0 years (23,741 days).
Specimen BA2491D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5560d29-429b-4263-9199-9610b5ea2476.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2453D (Solid Tissue Normal), aliquot aq-BA2453D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3cf1b45f-32a1-40be-ba93-4c0e1c3d6c15

The open-access MAF lists 21 somatic variants for this specimen: 18 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, 3'UTR 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYLD | c.2305A>T p.I769F | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as rs1489875475, CD051729, COSV61093604, COSV61095598; called by muse, mutect2, varscan2
- EPHA2 | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 110/280 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as rs975323516; called by muse, varscan2
- GNAS | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as CM940874, COSV55677425, COSV55683375; called by muse, mutect2, varscan2
- RHBDL2 | c.299C>T p.T100M | Missense Mutation (SNP) | VAF 66/154 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs749190576; called by muse, mutect2, varscan2
- SRA1 | c.8G>T p.R3L | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV60365354; called by muse, mutect2
- AHNAK2 | c.12931T>G p.S4311A | Missense Mutation (SNP) | VAF 93/587 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BCO2 | c.503C>A p.P168H | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- CELSR3 | c.7129G>T p.V2377F | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2
- DPH2 | c.693C>A p.D231E | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); called by muse, mutect2
- ETV2 | c.383C>A p.A128E | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.009); called by muse, mutect2
- MON1A | c.1279G>T p.V427L | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); called by muse, mutect2
- MON2 | c.3971C>A p.T1324N | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.084); called by muse, mutect2
- SLC20A1 | c.1211T>C p.M404T | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- TFAP2A | c.572C>T p.A191V (on ENST00000482890; = p.A183V on NM_001032280.3) | Missense Mutation (SNP) | VAF 44/174 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.018); called by muse, varscan2
- TMEM132C | c.1189G>A p.G397R | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- TOPAZ1 | c.14C>A p.P5Q | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.007); called by muse, mutect2
- ZNF197 | c.1083A>C p.L361F | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- ZSWIM4 | c.2370G>C p.Q790H | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.219); called by muse, mutect2
- NACC2 | c.168C>T p.R56= | Silent (SNP) | VAF 48/81 reads (59%) | catalogued as rs1204581865; called by muse, mutect2, varscan2
- IGSF22 | c.*22C>T | 3'UTR (SNP) | VAF 61/293 reads (21%) | catalogued as rs773708398, COSV99773850; called by muse, mutect2, varscan2
- TNFRSF12A | c.*19C>A | 3'UTR (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2
